Gene-level copy-number profile of tumor specimen TCGA-LN-A7HW-01A from TCGA case TCGA-LN-A7HW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 59.8 years (21,840 days).
Specimen TCGA-LN-A7HW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.98e967f1-3fae-4bc0-a4eb-cdea529b259f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A7HW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c803e8c5-f5b9-49c4-9862-8f088f1e694c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 998; copy number 2: 22,771; copy number 3: 10,233; copy number 4: 22,330; copy number 5: 1,468; copy number 6: 419; copy number 7: 20; copy number 8: 330; copy number 9: 472; copy number 10: 620; copy number 11: 29; copy number 14: 26; copy number 21: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A7HW-01A-22D-A350-01): tumor purity 0.62, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr4:21,843,341–22,330,330, 3 genes: KCNIP4-IT1, AC096719.1, RNU6-420P.
- chr4:90,370,123–90,683,123, 2 genes: RN7SKP248, AC093729.1.
- chr8:4,496,392–4,788,584, 3 genes: AC010941.1, AC022068.1, PAICSP4.
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,716,105–25,844,585, 80 genes (within-gene range 0–2) (broad region; genes not listed).
- chr10:51,319,826–51,320,660, 1 gene: RSU1P3.
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,150 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,773,396–198,222,513, 578 genes, copy number 10 (broad region; genes not listed).
- chr5:58,198–9,045,940, 186 genes, copy number 9 (broad region; genes not listed).
- chr5:9,053,816–9,053,895, 1 gene, copy number 9: MIR4636.
- chr5:27,217,714–45,895,970, 285 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr8:46,028,804–47,068,323, 20 genes, copy number 10: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32.
- chr11:69,641,156–70,436,584, 27 genes, copy number 11: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,604,859, 2 genes, copy number 11: AP001271.1, AP001271.2.
- chr12:14,169,746–15,348,675, 32 genes, copy number 10–14: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1.
- chr12:15,620,134–15,882,329, 1 gene, copy number 21 (within-gene range 4–21): EPS8.
- chr12:15,780,068–15,804,158, 2 genes, copy number 21: AC073651.1, AC073651.2.
- chr17:61,942,605–62,416,480, 16 genes, copy number 10: MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
